Somatic mutation profile of tumor specimen 0DLFB4 from CCDI case PBBYUU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 14.6 years (5,332 days).
Specimen 0DLFB4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3bd3f1b-75e0-4587-8b95-742c0571e1ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLFAY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2acb9153-b1e2-4370-ba24-5c8dd1560d5b

The open-access MAF lists 90 somatic variants for this specimen: 61 protein-altering or splice-affecting, 16 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 16, Intron 5, 5'UTR 3, 5'Flank 3, Nonsense Mutation 3, 3'UTR 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTR3 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 394/2054 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.357); catalogued as COSV54298524, COSV54301422; called by muse, varscan2
- ARC | c.667C>T p.H223Y | Missense Mutation (SNP) | VAF 147/349 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs1370501987, COSV63079933; called by muse, mutect2, varscan2
- BPIFB1 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 245/1272 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.07); catalogued as rs373099188; called by muse, mutect2, varscan2
- CCNP | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 55/857 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs773431582; called by muse, mutect2
- G6PC2 | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 128/1427 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.894); catalogued as rs781373483; called by muse, mutect2
- GAB4 | c.562C>T p.Q188* | Nonsense Mutation (SNP) | VAF 38/1464 reads (3%) | catalogued as rs1032243450; called by muse, mutect2
- KCND3 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 45/568 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56183584; called by muse, mutect2
- KMT2D | c.6017G>T p.W2006L | Missense Mutation (SNP) | VAF 205/814 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99986220; called by muse, mutect2, varscan2
- LAMA5 | c.3346G>A p.A1116T | Missense Mutation (SNP) | VAF 134/1246 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.473); catalogued as rs755003891; called by muse, mutect2, varscan2
- LILRB5 | c.161A>G p.E54G | Missense Mutation (SNP) | VAF 125/519 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.024); catalogued as rs1240317564; called by muse, mutect2, varscan2
- MAGEB10 | c.686C>T p.T229M | Missense Mutation (SNP) | VAF 257/656 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs761828309, COSV63310904; called by muse, mutect2, varscan2
- MYH9 | c.3964C>T p.R1322W | Missense Mutation (SNP) | VAF 99/1708 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201269631; called by muse, mutect2
- NETO1 | c.868C>G p.P290A | Missense Mutation (SNP) | VAF 135/607 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.328); catalogued as rs1459765500, COSV55016516; called by muse, mutect2, varscan2
- NLRP8 | c.2359C>T p.R787W | Missense Mutation (SNP) | VAF 95/658 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as rs183661608, COSV52585764; called by muse, mutect2
- NUTM1 | c.2131G>T p.G711W | Missense Mutation (SNP) | VAF 22/362 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1387991316; called by muse, mutect2
- OR4D5 | c.242T>A p.M81K | Missense Mutation (SNP) | VAF 244/1019 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs370700987; called by muse, mutect2, varscan2
- OSBPL6 | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 71/1444 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1481226098; called by muse, mutect2
- PIK3CG | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 84/824 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs747797529, COSV63246938; called by muse, mutect2
- PSMG3 | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 58/812 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as rs774824741; called by muse, mutect2
- RASAL3 | c.472C>T p.R158* | Nonsense Mutation (SNP) | VAF 75/396 reads (19%) | catalogued as rs756096492, COSV59141603; called by muse, mutect2, varscan2
- RNF17 | c.1507A>G p.T503A | Missense Mutation (SNP) | VAF 214/862 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs140650415; called by muse, mutect2, varscan2
- RSPH10B2 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 221/465 reads (48%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.592); catalogued as rs757582678, COSV51871465; called by muse, mutect2, varscan2
- RYR1 | c.6407G>A p.R2136H | Missense Mutation (SNP) | VAF 70/413 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs530885842, COSV62103633; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.2786G>A p.R929H | Missense Mutation (SNP) | VAF 1452/1593 reads (91%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as rs876657988, CM1513505, COSV63669492; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMEM100 | c.59C>A p.T20K | Missense Mutation (SNP) | VAF 193/674 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0.062); catalogued as rs754310604; called by muse, mutect2, varscan2
- UNC13D | c.954G>A p.A318= | Splice Region (SNP) | VAF 30/352 reads (9%) | catalogued as rs751058445, COSV52884034, COSV99256658; ClinVar: uncertain significance; called by muse, mutect2
- ZNF408 | c.1823G>A p.R608H | Missense Mutation (SNP) | VAF 88/757 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as rs763950014, COSV61239586; called by muse, mutect2, varscan2
- ZNF433 | c.1244C>T p.T415I | Missense Mutation (SNP) | VAF 96/503 reads (19%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.995); catalogued as rs372568825; called by muse, mutect2, varscan2
- ACAA1 | c.541A>G p.M181V | Missense Mutation (SNP) | VAF 86/292 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- ANKRD30B | c.2880G>T p.R960S | Missense Mutation (SNP) | VAF 146/1378 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.06); called by mutect2, varscan2
- ATG2B | c.5396C>T p.A1799V | Missense Mutation (SNP) | VAF 25/975 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2
- BZW2 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 225/1038 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CACNA1I | c.3372C>G p.Y1124* | Nonsense Mutation (SNP) | VAF 82/626 reads (13%) | called by muse, mutect2, varscan2
- CAVIN1 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 44/307 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- CCDC39 | c.1548G>T p.K516N | Missense Mutation (SNP) | VAF 105/720 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- CYSLTR2 | c.476G>A p.C159Y | Missense Mutation (SNP) | VAF 135/915 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DDX21 | c.875T>G p.F292C | Missense Mutation (SNP) | VAF 175/2077 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- DENND1B | c.1177A>T p.N393Y | Missense Mutation (SNP) | VAF 524/1642 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DOCK9 | c.209G>C p.R70P (on ENST00000376460 / NM_001366676.2; = p.R71P on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 178/1298 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FOXQ1 | c.293C>A p.P98Q | Missense Mutation (SNP) | VAF 43/226 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- GABARAPL1 | c.138G>C p.K46N | Missense Mutation (SNP) | VAF 216/611 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- HERC2 | c.7046A>T p.Q2349L | Missense Mutation (SNP) | VAF 42/1333 reads (3%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- KIAA2012 | c.536T>C p.I179T | Missense Mutation (SNP) | VAF 175/1003 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- MAP2 | c.3276G>A p.M1092I | Missense Mutation (SNP) | VAF 127/1226 reads (10%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MORN3 | c.346G>A p.G116S | Missense Mutation (SNP) | VAF 345/645 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC12 | c.687C>G p.S229R (on ENST00000379442; = p.S86R on NM_001164462.1) | Missense Mutation (SNP) | VAF 238/1002 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- MYCBP2 | c.5968C>T p.P1990S (on ENST00000357337; = p.P2028S on NM_015057.5) | Missense Mutation (SNP) | VAF 153/1146 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- NCKAP1L | c.2888C>A p.A963E | Missense Mutation (SNP) | VAF 187/709 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- NEO1 | c.781G>A p.V261I | Missense Mutation (SNP) | VAF 65/1336 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.088); called by muse, mutect2
- OR52E8 | c.227A>T p.D76V | Missense Mutation (SNP) | VAF 318/1160 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- P2RX1 | c.70G>C p.V24L | Missense Mutation (SNP) | VAF 169/446 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PASD1 | c.2040A>G p.I680M | Missense Mutation (SNP) | VAF 216/497 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- PTCHD3 | c.1090-1G>C p.X364_splice | Splice Site (SNP) | VAF 110/1259 reads (9%) | called by muse, mutect2
- RXFP3 | c.938C>A p.P313Q | Missense Mutation (SNP) | VAF 92/628 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.166); called by mutect2, varscan2
- SLC25A27 | c.537A>T p.K179N | Missense Mutation (SNP) | VAF 161/1172 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- TIAM1 | c.995C>A p.A332E | Missense Mutation (SNP) | VAF 324/1130 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMC4 | c.553A>G p.T185A (on ENST00000617472 / NM_001145303.3; = p.T179A on NM_144686.4) | Missense Mutation (SNP) | VAF 89/546 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- USH2A | c.4677T>G p.F1559L | Missense Mutation (SNP) | VAF 84/2058 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.005); called by muse, mutect2
- USP33 | c.2590G>A p.G864S | Missense Mutation (SNP) | VAF 383/1139 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- XYLB | c.1430C>A p.A477D | Missense Mutation (SNP) | VAF 122/525 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF763 | c.199A>G p.I67V (on ENST00000358987 / NM_001367172.2; = p.I70V on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/1364 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.034); called by muse, mutect2
- CILP2 | c.216C>T p.G72= | Silent (SNP) | VAF 93/633 reads (15%) | called by muse, mutect2, varscan2
- COL11A1 | c.4596T>C p.P1532= | Silent (SNP) | VAF 141/1260 reads (11%) | catalogued as COSV62171535; called by muse, mutect2, varscan2
- DGCR8 | c.1236G>A p.G412= | Silent (SNP) | VAF 42/1013 reads (4%) | called by muse, mutect2
- DLGAP4 | c.411C>A p.G137= | Silent (SNP) | VAF 150/1185 reads (13%) | called by muse, mutect2, varscan2
- MARCHF10 | c.525C>T p.P175= | Silent (SNP) | VAF 116/684 reads (17%) | called by muse, mutect2, varscan2
- MYORG | c.537C>A p.G179= | Silent (SNP) | VAF 78/190 reads (41%) | catalogued as rs1422440223, COSV52628101; called by muse, mutect2, varscan2
- NXNL2 | c.441G>A p.A147= | Silent (SNP) | VAF 161/384 reads (42%) | catalogued as rs376120424; called by muse, mutect2, varscan2
- PLOD2 | c.480G>A p.G160= | Silent (SNP) | VAF 116/825 reads (14%) | called by muse, mutect2, varscan2
- SLC4A4 | c.1467A>G p.G489= (on ENST00000264485 / NM_001098484.3; = p.G445= on NM_003759.4) | Silent (SNP) | VAF 320/1075 reads (30%) | called by muse, mutect2, varscan2
- SLC6A13 | c.1203G>A p.A401= | Silent (SNP) | VAF 258/921 reads (28%) | catalogued as rs140923338; called by muse, mutect2, varscan2
- STK31 | c.1044G>A p.L348= | Silent (SNP) | VAF 112/1064 reads (11%) | called by muse, mutect2, varscan2
- SULT2A1 | c.459T>C p.F153= | Silent (SNP) | VAF 87/1084 reads (8%) | called by muse, mutect2
- TECTA | c.2175C>T p.D725= | Silent (SNP) | VAF 107/891 reads (12%) | catalogued as rs865971914, COSV50691745; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTLL1 | c.399C>T p.S133= | Silent (SNP) | VAF 309/1382 reads (22%) | called by muse, mutect2, varscan2
- TUBG2 | c.1068C>T p.I356= | Silent (SNP) | VAF 36/884 reads (4%) | called by muse, mutect2
- UBE3C | c.1032G>C p.V344= | Silent (SNP) | VAF 165/972 reads (17%) | called by muse, mutect2, varscan2
- CADM1 | chr11:115504476 C>A | 5'Flank (SNP) | VAF 17/54 reads (31%) | called by muse, mutect2, varscan2
- HM13 | c.365+159G>A | Intron (SNP) | VAF 168/962 reads (17%) | called by muse, mutect2, varscan2
- LSM14A | c.-15G>T | 5'UTR (SNP) | VAF 21/189 reads (11%) | catalogued as COSV70885413; called by muse, mutect2, varscan2
- MDFIC | c.-277G>A | 5'UTR (SNP) | VAF 74/790 reads (9%) | called by muse, mutect2
- MKLN1 | chr7:131327830 C>T | 5'Flank (SNP) | VAF 17/75 reads (23%) | called by muse, mutect2, varscan2
- MS4A4E | chr11:60230061 C>A | 5'Flank (SNP) | VAF 46/762 reads (6%) | called by muse, mutect2
- PAX8 | c.1189+88C>T | Intron (SNP) | VAF 15/132 reads (11%) | catalogued as rs1485312463; called by muse, mutect2, varscan2
- PCDHB1 | c.*33G>A | 3'UTR (SNP) | VAF 90/404 reads (22%) | catalogued as rs879954005; called by muse, mutect2, varscan2
- PTPN20 | c.35-39T>A | Intron (SNP) | VAF 42/798 reads (5%) | called by muse, mutect2
- RFC1 | c.-43G>A | 5'UTR (SNP) | VAF 21/572 reads (4%) | catalogued as rs1288646838; called by muse, mutect2
- SHISA9 | c.563+5988G>A | Intron (SNP) | VAF 128/227 reads (56%) | catalogued as rs371077772; called by muse, mutect2, varscan2
- ZNF652 | c.*67G>A | 3'UTR (SNP) | VAF 75/206 reads (36%) | catalogued as rs537472151; called by muse, mutect2, varscan2
- ZNF671 | c.138+47C>T | Intron (SNP) | VAF 45/232 reads (19%) | catalogued as rs1417776148; called by muse, mutect2, varscan2
